Somatic mutation profile of tumor specimen TCGA-EE-A3AE-06A (aliquot TCGA-EE-A3AE-06A-11D-A196-08) from TCGA case TCGA-EE-A3AE, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 54.6 years (19,957 days).
Specimen TCGA-EE-A3AE-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7895545e-0b3c-42a6-a590-c7e4d4de9af7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A3AE-10A (Blood Derived Normal), aliquot TCGA-EE-A3AE-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/642ce8ec-cc0d-4596-a81f-7fe32a660f31

The open-access MAF lists 1,764 somatic variants for this specimen: 1,132 protein-altering or splice-affecting, 595 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,047, Silent 595, Nonsense Mutation 58, RNA 17, Intron 14, Splice Region 14, Splice Site 8, 5'Flank 3, 3'Flank 2, Translation Start Site 1, 3'UTR 1, Frame Shift Ins 1.

Variants (750 of 1,764; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALAS2 | c.475G>A p.D159N | Missense Mutation (SNP) | VAF 40/69 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs137852308, CM023002, CM036013, COSV58193257; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APOB | c.9175C>T p.R3059C | Missense Mutation (SNP) | VAF 123/276 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs146377316, CM127717, COSV51947017; ClinVar: likely pathogenic / uncertain significance; called by mutect2, varscan2
- CDKN2A | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 130/160 reads (81%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913386, CM983988, COSV58683051, COSV58690307, COSV58692178; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- GJB2 | c.94C>T p.R32C | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371024165, CM002993, CM108184; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 33/43 reads (77%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- A4GALT | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs771775510, COSV50745030; called by muse, mutect2, varscan2
- ABCA6 | c.4774G>A p.E1592K | Missense Mutation (SNP) | VAF 28/33 reads (85%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.795); catalogued as COSV52644007, COSV52644344, COSV52644677; called by muse, mutect2, varscan2
- ABCA8 | c.1691C>T p.P564L | Missense Mutation (SNP) | VAF 77/85 reads (91%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52211840; called by muse, mutect2, varscan2
- ABCB11 | c.3292G>A p.G1098S | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV55600761; called by muse, mutect2, varscan2
- ABCB5 | c.2847G>A p.M949I (on ENST00000404938 / NM_001163941.2; = p.M504I on NM_178559.6) | Missense Mutation (SNP) | VAF 32/51 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs865785905, COSV51720516; called by muse, mutect2, varscan2
- ABCB6 | c.1226T>G p.F409C | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54700290; called by muse, mutect2, varscan2
- ABCB7 | c.302G>A p.G101E (on ENST00000373394 / NM_001271696.3; = p.G102E on NM_004299.6) | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV53718589, COSV99504376; called by muse, mutect2, varscan2
- ABCC1 | c.3966+1G>A p.X1322_splice | Splice Site (SNP) | VAF 6/30 reads (20%) | catalogued as COSV60693822; called by muse, mutect2, varscan2
- ABCC2 | c.4616A>T p.N1539I | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.08); catalogued as COSV100966655; called by muse, mutect2, varscan2
- ABCC9 | c.68C>T p.S23F | Missense Mutation (SNP) | VAF 31/35 reads (89%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV53968664; called by muse, mutect2, varscan2
- ABCE1 | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 43/78 reads (55%) | catalogued as COSV56847612; called by muse, mutect2, varscan2
- ABCG8 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 112/209 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV55396696; called by muse, mutect2, varscan2
- AC097636.1 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV71309492; called by muse, mutect2, varscan2
- AC244197.3 | c.943G>A p.D315N | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0.043); catalogued as CD983363, COSV61714583; called by muse, mutect2, varscan2
- ACAD10 | c.1661C>T p.S554F | Missense Mutation (SNP) | VAF 53/62 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV58162656; called by muse, mutect2, varscan2
- ACER1 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs866874353, COSV56836966; called by muse, mutect2, varscan2
- ACKR2 | c.56A>T p.N19I | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as COSV56180293; called by muse, varscan2
- ACSF3 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 47/69 reads (68%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as rs754865511, COSV100441496; called by muse, mutect2, varscan2
- ACSM2A | c.317G>A p.G106E (on ENST00000219054; = p.G27E on NM_001308169.2) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54589681; called by muse, mutect2, varscan2
- ADA2 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 69/95 reads (73%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as rs1285480967, COSV52830695; called by muse, mutect2, varscan2
- ADAM19 | c.2459G>A p.G820E | Missense Mutation (SNP) | VAF 32/55 reads (58%) | SIFT tolerated (0.44); PolyPhen benign (0.018); catalogued as COSV57438989; called by muse, mutect2, varscan2
- ADAM21 | c.791G>A p.G264E | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT tolerated (0.83); PolyPhen benign (0.02); catalogued as rs762521545, COSV50809100; called by muse, mutect2, varscan2
- ADAM7 | c.536C>T p.T179I | Missense Mutation (SNP) | VAF 50/75 reads (67%) | SIFT tolerated (0.47); PolyPhen benign (0.057); catalogued as rs868821595, COSV51536734; called by muse, varscan2
- ADAM7 | c.1466G>A p.G489E | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51546531; called by muse, mutect2, varscan2
- ADAMTS10 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 47/76 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1279202450, COSV54353125; called by muse, mutect2, varscan2
- ADAMTS19 | c.3112G>A p.E1038K | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.492); catalogued as COSV50796847; called by muse, mutect2, varscan2
- ADGRE3 | c.1051G>A p.E351K | Missense Mutation (SNP) | VAF 18/30 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.02); catalogued as COSV53734691; called by muse, varscan2
- ADGRG4 | c.3164C>T p.S1055F | Missense Mutation (SNP) | VAF 41/73 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.496); catalogued as COSV54966483; called by muse, mutect2, varscan2
- ADGRL2 | c.3626G>A p.G1209E (on ENST00000370717 / NM_001366005.1; = p.G1153E on NM_012302.4) | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.579); catalogued as rs969053627, COSV54662257, COSV54688671; called by muse, mutect2, varscan2
- ADGRV1 | c.9349G>A p.V3117I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV67995133; called by muse, mutect2, varscan2
- ADH1A | c.1025C>T p.S342L | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV52924289; called by muse, mutect2, varscan2
- ADRB1 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65168336; called by muse, mutect2, varscan2
- AGBL5 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59936201, COSV59938349; called by muse, mutect2, varscan2
- AHNAK | c.6544C>T p.P2182S | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV57229853; called by muse, mutect2, varscan2
- AHSG | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as COSV56609392; called by muse, mutect2, varscan2
- AKAP13 | c.3991G>A p.E1331K | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); catalogued as COSV63469467; called by muse, mutect2, varscan2
- AKAP6 | c.6332C>T p.S2111L | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs773070431, COSV55206503; called by muse, mutect2, varscan2
- ALG13 | c.1679G>A p.R560Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.704); catalogued as COSV52644920; called by muse, mutect2, varscan2
- ALPK3 | c.3842G>A p.R1281Q | Missense Mutation (SNP) | VAF 44/67 reads (66%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs267604354, COSV51939596; called by muse, mutect2, varscan2
- AMBN | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.705); catalogued as COSV59828095; called by muse, varscan2
- AMER3 | c.215T>G p.L72R | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.48); PolyPhen benign (0.012); catalogued as COSV58469968; called by muse, mutect2, varscan2
- AMY1C | c.988T>G p.F330V | Missense Mutation (SNP) | VAF 63/265 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64407523; called by muse, mutect2, varscan2
- AMY2B | c.1379C>T p.P460L | Missense Mutation (SNP) | VAF 47/457 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV63717034; called by muse, mutect2, varscan2
- ANAPC1 | c.4972C>T p.P1658S | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.123); catalogued as rs1299654211, COSV61976746; called by mutect2, varscan2
- ANGPTL5 | c.839G>A p.G280E | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57534574; called by muse, mutect2
- ANK1 | c.4855G>A p.E1619K | Missense Mutation (SNP) | VAF 85/135 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); catalogued as COSV55885851; called by muse, mutect2, varscan2
- ANK3 | c.10657G>A p.E3553K | Missense Mutation (SNP) | VAF 20/32 reads (63%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); catalogued as rs376597004; called by muse, mutect2, varscan2
- ANK3 | c.5177C>T p.P1726L | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.997); catalogued as rs1232915389, COSV55080802; called by muse, mutect2, varscan2
- ANK3 | c.3526C>T p.R1176* (on ENST00000280772 / NM_001320874.2; = p.R310* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 27/56 reads (48%) | catalogued as rs142673853, COSV55052053; called by muse, mutect2, varscan2
- ANKIB1 | c.2530C>T p.Q844* | Nonsense Mutation (SNP) | VAF 66/109 reads (61%) | catalogued as COSV56065993; called by muse, mutect2, varscan2
- ANKRD17 | c.1163A>G p.E388G | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.896); catalogued as COSV58227603; called by muse, mutect2, varscan2
- ANO10 | c.1346C>T p.S449F | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV52736238; called by muse, mutect2, varscan2
- ANO4 | c.827G>A p.G276E (on ENST00000392977 / NM_001286615.2; = p.G241E on NM_178826.4) | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.974); catalogued as COSV54612988; called by muse, mutect2, varscan2
- ANO4 | c.1446G>A p.M482I (on ENST00000392977 / NM_001286615.2; = p.M447I on NM_178826.4) | Missense Mutation (SNP) | VAF 41/45 reads (91%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as COSV54612995; called by muse, mutect2, varscan2
- ANO4 | c.2086G>A p.E696K (on ENST00000392977 / NM_001286615.2; = p.E661K on NM_178826.4) | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54595649; called by muse, mutect2, varscan2
- ANOS1 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as rs143406724, COSV52926229, COSV99390763; called by mutect2, varscan2
- ANTXR1 | c.1325C>T p.S442F | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.697); catalogued as rs763210251, COSV58013926; called by muse, mutect2, varscan2
- APBA2 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101258199; called by muse, mutect2, varscan2
- APC2 | c.3140C>T p.P1047L | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV52022024, COSV99279739; called by muse, mutect2, varscan2
- APCDD1L | c.1303G>A p.G435S | Missense Mutation (SNP) | VAF 114/234 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64487912; called by muse, mutect2, varscan2
- APOA4 | c.1120G>A p.E374K | Missense Mutation (SNP) | VAF 102/315 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.034); catalogued as COSV63360108; called by muse, mutect2, varscan2
- APOBR | c.2906G>A p.G969D (on ENST00000431282; = p.G978D on NM_018690.4) | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60493908; called by muse, mutect2, varscan2
- AQP9 | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT tolerated (0.86); PolyPhen benign (0.03); catalogued as COSV54970993; called by muse, mutect2, varscan2
- ARAP2 | c.3697C>T p.P1233S | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.365); catalogued as rs748240394, COSV58291989; called by muse, mutect2, varscan2
- AREG | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 49/180 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs765591544, COSV52644609; called by muse, mutect2, varscan2
- ARHGEF10L | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 117/249 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); catalogued as COSV51440316; called by muse, mutect2, varscan2
- ARHGEF12 | c.1249G>A p.E417K | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63107295; called by muse, mutect2, varscan2
- ARHGEF17 | c.5096C>T p.P1699L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV55237971; called by muse, mutect2, varscan2
- ARHGEF25 | c.1129C>T p.R377* | Nonsense Mutation (SNP) | VAF 53/61 reads (87%) | catalogued as rs1293298145, COSV54090474; called by muse, mutect2, varscan2
- ARL13A | c.611C>T p.S204F | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.246); catalogued as COSV65880349; called by muse, mutect2, varscan2
- ARMC4 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as COSV59470683; called by muse, mutect2, varscan2
- ARNT2 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 91/125 reads (73%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as rs1429600637, COSV57582718; called by muse, mutect2, varscan2
- ARPP21 | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV51796352; called by muse, mutect2, varscan2
- ARX | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.115); catalogued as COSV66875800; called by muse, mutect2, varscan2
- ASAP1 | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 106/166 reads (64%) | SIFT tolerated (0.63); PolyPhen benign (0.084); catalogued as COSV63054305; called by muse, mutect2, varscan2
- ASB10 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs755804051, COSV52000326; called by muse, mutect2, varscan2
- ASB12 | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.641); catalogued as COSV62857724; called by muse, mutect2, varscan2
- ASCC1 | c.523C>T p.Q175* (on ENST00000342444 / NM_001369085.1; = p.Q147* on NM_001198798.2 and 8 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as rs937013345, COSV57728888; called by mutect2, varscan2
- ASXL3 | c.6514G>A p.E2172K | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV52479127; called by muse, mutect2, varscan2
- ATF7 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.659); catalogued as COSV60646316; called by muse, mutect2, varscan2
- ATG16L1 | c.642G>A p.R214= | Splice Region (SNP) | VAF 22/83 reads (27%) | catalogued as COSV61468039, COSV61468154; called by muse, mutect2, varscan2
- ATG7 | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 95/163 reads (58%) | SIFT tolerated (0.15); PolyPhen benign (0.386); catalogued as rs751642577, COSV100607132, COSV61615655; called by muse, mutect2, varscan2
- ATP11C | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV59573187; called by muse, mutect2, varscan2
- ATP13A2 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58703607; called by muse, mutect2, varscan2
- ATP13A5 | c.2605G>A p.E869K | Missense Mutation (SNP) | VAF 52/85 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs1484164068, COSV60875294; called by muse, mutect2, varscan2
- ATP2B4 | c.2711C>T p.P904L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV58183714; called by muse, mutect2, varscan2
- ATP5PB | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs751833359, COSV52384704; called by muse, mutect2, varscan2
- ATP8A2 | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54976187; called by muse, mutect2, varscan2
- ATP9A | c.1669G>A p.D557N | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.079); catalogued as COSV58771733; called by muse, mutect2, varscan2
- ATR | c.5953C>T p.P1985S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0.101); catalogued as COSV63392186; called by muse, mutect2, varscan2
- ATR | c.1322C>T p.S441F | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); catalogued as COSV63392189; called by muse, mutect2, varscan2
- AXDND1 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs868380930, COSV62648005; called by muse, mutect2, varscan2
- AZGP1 | c.418G>A p.D140N | Missense Mutation (SNP) | VAF 159/251 reads (63%) | SIFT tolerated (0.07); PolyPhen benign (0.152); catalogued as COSV52797805; called by muse, mutect2, varscan2
- BCAM | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.684); catalogued as COSV54304827; called by muse, mutect2, varscan2
- BCAS1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 75/167 reads (45%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.486); catalogued as COSV65085834; called by muse, mutect2, varscan2
- BCL11B | c.1987G>A p.E663K (on ENST00000357195 / NM_001282237.2; = p.E592K on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.179); catalogued as COSV61739249; called by muse, mutect2, varscan2
- BNC1 | c.1369C>T p.P457S | Missense Mutation (SNP) | VAF 48/65 reads (74%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV61759124; called by muse, mutect2, varscan2
- BNC1 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.122); catalogued as rs536657331, COSV61759128; called by muse, mutect2, varscan2
- BOD1L1 | c.6221C>T p.S2074F | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50062741; called by muse, mutect2, varscan2
- BPIFB2 | c.1258G>A p.A420T | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs1327804666, COSV50070644; called by muse, mutect2, varscan2
- BRPF1 | c.2626C>T p.P876S | Missense Mutation (SNP) | VAF 49/219 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs751579661, COSV57407992; called by muse, mutect2, varscan2
- BTK | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 40/106 reads (38%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.671); catalogued as COSV58118425; called by muse, mutect2, varscan2
- C10orf120 | c.119T>G p.F40C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.079); catalogued as COSV61492613; called by muse, mutect2
- C10orf71 | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 36/62 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.07); catalogued as COSV60513010; called by muse, mutect2, varscan2
- C10orf71 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV60513029; called by muse, mutect2, varscan2
- C10orf90 | c.1889C>T p.P630L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52963855; called by muse, mutect2, varscan2
- C14orf39 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs147627198, COSV58779891; called by muse, mutect2, varscan2
- C19orf44 | c.911C>T p.S304F | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV55614875; called by muse, mutect2, varscan2
- C1QTNF2 | c.311G>A p.R104Q (on ENST00000393975; = p.R59Q on NM_031908.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.13); PolyPhen benign (0.024); catalogued as rs759937511, COSV67432358; called by muse, mutect2, varscan2
- C3 | c.115G>A p.E39K | Missense Mutation (SNP) | VAF 59/98 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.185); catalogued as rs771084936, COSV55581223; called by muse, mutect2, varscan2
- C5AR2 | c.635C>T p.P212L | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57257280; called by muse, mutect2, varscan2
- C6 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as rs369381506; called by muse, varscan2
- C7 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs192679722, COSV57480739; ClinVar: uncertain significance; called by mutect2, varscan2
- C8B | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64776698; called by muse, mutect2, varscan2
- C9 | c.769G>A p.E257K | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV54674942; called by muse, mutect2, varscan2
- CACNA1C | c.5173C>T p.Q1725* | Nonsense Mutation (SNP) | VAF 17/23 reads (74%) | catalogued as rs1556102869, COSV59769194; called by muse, mutect2, varscan2
- CACNA1E | c.5827C>T p.P1943S | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.035); catalogued as rs549170593, COSV100704124, COSV62419963; called by mutect2, varscan2
- CACNA1E | c.5828C>T p.P1943L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.253); catalogued as COSV100704535; called by muse, mutect2, varscan2
- CACNA1F | c.1959G>A p.M653I | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.954); catalogued as rs1557109128, COSV59906950; called by muse, mutect2, varscan2
- CACNA2D2 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1340066055, COSV56569065; called by muse, mutect2, varscan2
- CACNA2D3 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55535998, COSV55580939; called by muse, mutect2, varscan2
- CACNA2D4 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 73/90 reads (81%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.97); catalogued as COSV54959809; called by muse, mutect2, varscan2
- CADPS2 | c.3569G>A p.R1190Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1292221184, COSV57361913, COSV57385338; called by muse, mutect2
- CAMK1G | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.25); catalogued as COSV50526444; called by muse, mutect2, varscan2
- CAPN13 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV54428562; called by muse, mutect2, varscan2
- CARD11 | c.1273G>A p.E425K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); catalogued as COSV67802414; called by muse, mutect2, varscan2
- CARD11 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 32/152 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.776); catalogued as COSV67802419, COSV67802506; called by muse, mutect2, varscan2
- CASR | c.2827G>A p.E943K (on ENST00000490131; = p.E1020K on NM_000388.4) | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); catalogued as rs1060502858, COSV56141388; called by muse, mutect2, varscan2
- CBARP | c.1114C>T p.P372S (on ENST00000382477; = p.P352S on NM_152769.3) | Missense Mutation (SNP) | VAF 40/68 reads (59%) | SIFT tolerated (0.87); PolyPhen benign (0.092); catalogued as COSV53070671, COSV53071589; called by muse, mutect2, varscan2
- CBLIF | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57240365; called by muse, varscan2
- CBWD5 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 31/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101070735; called by muse, mutect2, varscan2
- CBWD5 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101070734; called by mutect2, varscan2
- CCDC141 | c.4067C>A p.T1356N | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.519); catalogued as COSV55382048; called by muse, mutect2, varscan2
- CCDC141 | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as rs914187336, COSV55370770; called by muse, mutect2, varscan2
- CCDC141 | c.3298G>A p.V1100I | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV55382092; called by muse, mutect2, varscan2
- CCDC141 | c.2107G>A p.E703K | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.714); catalogued as rs1371281003, COSV55382110; called by muse, mutect2, varscan2
- CCDC54 | c.676C>T p.Q226* | Nonsense Mutation (SNP) | VAF 44/79 reads (56%) | catalogued as COSV53759831; called by muse, mutect2, varscan2
- CCDC93 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV60124156; called by muse, mutect2, varscan2
- CCM2L | c.1192C>T p.H398Y (on ENST00000452892 / NM_001365692.1; = p.S376= on NM_080625.4) | Missense Mutation (SNP) | VAF 136/327 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs1047957167, COSV52952650; called by muse, mutect2, varscan2
- CCT8L2 | c.1507G>A p.G503R | Missense Mutation (SNP) | VAF 121/202 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV63462245, COSV63463775; called by muse, mutect2, varscan2
- CCT8L2 | c.1151G>A p.G384E | Missense Mutation (SNP) | VAF 61/106 reads (58%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.636); catalogued as COSV63461818; called by muse, mutect2, varscan2
- CD1A | c.406C>T p.Q136* | Nonsense Mutation (SNP) | VAF 34/55 reads (62%) | catalogued as rs760078033, COSV56864256; called by muse, mutect2, varscan2
- CD1E | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs1306810030, COSV63772850; called by muse, mutect2, varscan2
- CD86 | c.661G>A p.E221K (on ENST00000330540 / NM_175862.5; = p.E215K on NM_006889.4) | Missense Mutation (SNP) | VAF 73/121 reads (60%) | SIFT tolerated (0.41); PolyPhen benign (0.026); catalogued as rs763958444, COSV52610221; called by muse, mutect2, varscan2
- CDC42BPB | c.1342C>T p.R448W | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.04); catalogued as rs765630243, COSV63476759; called by muse, mutect2, varscan2
- CDC42EP3 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV54875690; called by muse, mutect2, varscan2
- CDCA3 | c.485C>T p.P162L | Missense Mutation (SNP) | VAF 109/127 reads (86%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV57530303; called by muse, mutect2, varscan2
- CDCP1 | c.523G>A p.G175R | Missense Mutation (SNP) | VAF 78/108 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765788136, COSV56108013; called by muse, mutect2, varscan2
- CDH10 | c.1942G>A p.E648K | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV52597187; called by muse, mutect2, varscan2
- CDH12 | c.613G>A p.G205R | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1161269651, COSV66446852; called by muse, mutect2, varscan2
- CDH18 | c.2206C>T p.Q736* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as rs762348492, COSV56922945, COSV99937365; called by muse, mutect2, varscan2
- CDH4 | c.2491C>T p.P831S | Missense Mutation (SNP) | VAF 37/95 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64655827, COSV64674188; called by muse, mutect2, varscan2
- CDS1 | c.932G>A p.R311Q | Missense Mutation (SNP) | VAF 54/103 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs776915359, COSV55690760; called by muse, mutect2, varscan2
- CEACAM20 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 73/386 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV57603270; called by muse, mutect2, varscan2
- CEACAM5 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55752618; called by muse, mutect2, varscan2
- CECR2 | c.3263G>A p.G1088E (on ENST00000342247 / NM_001290047.2; = p.G904E on NM_001290046.1) | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as COSV52847945; called by muse, mutect2, varscan2
- CENPI | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs759339222, COSV54506237, COSV99515446; called by muse, mutect2, varscan2
- CEP126 | c.2597C>T p.S866F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54830538; called by muse, mutect2, varscan2
- CEP350 | c.5281C>T p.Q1761* | Nonsense Mutation (SNP) | VAF 7/18 reads (39%) | catalogued as COSV62609583; called by muse, mutect2, varscan2
- CERKL | c.1453C>T p.P485S (on ENST00000339098 / NM_001030311.2; = p.P459S on NM_201548.5) | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.33); PolyPhen benign (0.009); catalogued as COSV59204139, COSV59213550; called by muse, mutect2, varscan2
- CFAP54 | c.7582G>A p.E2528K | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0.04); PolyPhen benign (0.14); catalogued as COSV61575149; called by muse, mutect2, varscan2
- CFAP74 | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 42/76 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.044); catalogued as COSV54572886; called by muse, mutect2, varscan2
- CFHR5 | c.1478G>A p.R493K | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT tolerated (0.15); PolyPhen benign (0.062); catalogued as COSV56828223; called by muse, mutect2, varscan2
- CHD6 | c.7781C>T p.S2594F | Missense Mutation (SNP) | VAF 97/212 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV64694344; called by muse, mutect2, varscan2
- CHRD | c.997C>T p.P333S | Missense Mutation (SNP) | VAF 21/32 reads (66%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV52607468; called by muse, mutect2, varscan2
- CHRD | c.2126G>A p.G709E | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52612381; called by muse, mutect2, varscan2
- CHRFAM7A | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 29/61 reads (48%) | catalogued as COSV100241491, COSV55398213; called by muse, mutect2, varscan2
- CHRNA5 | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 65/106 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs983271367, COSV55140569; called by muse, mutect2, varscan2
- CHRNA9 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1356763800, COSV59576189; called by muse, mutect2, varscan2
- CHST1 | c.842A>G p.N281S | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV57325192, COSV57325694; called by muse, mutect2, varscan2
- CKAP2L | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs1244452249, COSV56697056; called by muse, mutect2, varscan2
- CLASRP | c.423G>T p.L141F | Missense Mutation (SNP) | VAF 62/299 reads (21%) | SIFT tolerated (0.37); catalogued as COSV55518257; called by muse, varscan2
- CLCNKB | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1342277280, COSV65161775; called by muse, mutect2, varscan2
- CLDN20 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs538851441, COSV65697889; called by muse, mutect2, varscan2
- CLEC4F | c.322A>C p.K108Q | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.879); catalogued as COSV55481541; called by muse, mutect2, varscan2
- CLIP4 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.982); catalogued as rs1275578729, COSV60751937; called by muse, mutect2, varscan2
- CMTR2 | c.1528T>A p.F510I | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57605007; called by muse, mutect2, varscan2
- CNGA3 | c.845C>T p.S282F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV55624555; called by muse, mutect2, varscan2
- CNTN4 | c.2219G>A p.R740Q | Missense Mutation (SNP) | VAF 43/63 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs767987719, COSV61880927; called by muse, mutect2, varscan2
- CNTN5 | c.1136C>T p.S379F | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.702); catalogued as rs866845091, COSV54279011; called by muse, mutect2, varscan2
- CNTN5 | c.2825G>A p.G942E | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1436874415, COSV54275052, COSV99681181; called by muse, mutect2, varscan2
- CNTNAP2 | c.3731C>T p.P1244L | Missense Mutation (SNP) | VAF 40/62 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV62254834; called by muse, varscan2
- CNTNAP5 | c.2972G>A p.G991E | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70502008; called by muse, mutect2
- COBL | c.1865G>A p.G622E | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54358158; called by muse, mutect2, varscan2
- COL22A1 | c.1601C>T p.S534F | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.857); catalogued as rs778667471, COSV57325080; called by muse, mutect2, varscan2
- COL5A1 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 43/54 reads (80%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.971); catalogued as rs1554806121, COSV65674531; ClinVar: uncertain significance; called by muse, varscan2
- COL5A3 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV53418855; called by muse, mutect2
- COL6A3 | c.6404G>A p.R2135K | Missense Mutation (SNP) | VAF 188/414 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.76); catalogued as COSV55092035; called by muse, mutect2, varscan2
- COL7A1 | c.4322C>T p.P1441L | Missense Mutation (SNP) | VAF 67/105 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.01); catalogued as CD993036, COSV60402854; called by muse, mutect2, varscan2
- COL9A1 | c.2152G>A p.G718R | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100295860, COSV57892938; called by muse, mutect2, varscan2
- COL9A1 | c.509C>T p.S170L | Missense Mutation (SNP) | VAF 67/76 reads (88%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs780899445, COSV61831236; called by muse, mutect2, varscan2
- COLQ | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1179945416, COSV67526023; called by muse, mutect2, varscan2
- CPED1 | c.1231T>A p.F411I | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV60012918; called by muse, mutect2, varscan2
- CPS1 | c.4219C>T p.P1407S | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.129); catalogued as COSV51823987; called by muse, varscan2
- CRB2 | c.794G>A p.C265Y | Missense Mutation (SNP) | VAF 70/77 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63505477; called by muse, mutect2, varscan2
- CREB3L3 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs994318348, COSV50197963; called by muse, mutect2
- CREBRF | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.025); catalogued as COSV51636395; called by muse, mutect2, varscan2
- CRHR2 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 33/53 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1271899323, COSV59267761; called by muse, mutect2, varscan2
- CRNKL1 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 52/90 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs763086392, COSV55619227, COSV99844357; called by muse, mutect2, varscan2
- CRNN | c.1153C>T p.Q385* | Nonsense Mutation (SNP) | VAF 27/107 reads (25%) | catalogued as COSV55123807; called by muse, mutect2, varscan2
- CRTAM | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.077); catalogued as COSV57071353, COSV99911986; called by muse, mutect2, varscan2
- CRY2 | c.1139T>G p.V380G | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69889316; called by muse, varscan2
- CSMD2 | c.2626G>A p.G876R | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53960793; called by muse, varscan2
- CSMD3 | c.10409C>T p.S3470F (on ENST00000297405 / NM_001363185.1; = p.S3301F on NM_052900.3) | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT tolerated (0.1); PolyPhen benign (0.118); catalogued as COSV52167040, COSV52314853; called by muse, mutect2, varscan2
- CSMD3 | c.7400G>A p.G2467E (on ENST00000297405 / NM_001363185.1; = p.G2363E on NM_052900.3) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52314877; called by muse, mutect2, varscan2
- CTNNBL1 | c.1009C>T p.Q337* | Nonsense Mutation (SNP) | VAF 47/113 reads (42%) | catalogued as COSV63747260; called by muse, mutect2, varscan2
- CTNND2 | c.2962G>A p.E988K | Missense Mutation (SNP) | VAF 50/85 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as rs150013185; called by muse, mutect2, varscan2
- CTSG | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV53536136; called by muse, mutect2, varscan2
- CTSG | c.597G>A p.G199= | Splice Region (SNP) | VAF 29/98 reads (30%) | catalogued as rs139142097; called by muse, mutect2, varscan2
- CUX1 | c.2318C>T p.A773V | Missense Mutation (SNP) | VAF 45/155 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV52915355; called by muse, mutect2, varscan2
- CUZD1 | c.1531C>T p.R511C | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373802557, COSV59027858; called by muse, mutect2, varscan2
- CX3CR1 | c.176G>A p.S59N | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.723); catalogued as rs753866039, COSV64195263; called by muse, mutect2, varscan2
- CXCR1 | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); catalogued as rs552902470, COSV55281877; called by muse, mutect2, varscan2
- CXorf66 | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV65169777; called by muse, mutect2, varscan2
- CYBB | c.1235G>A p.G412E | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM106243, COSV101059802; called by muse, mutect2, varscan2
- CYP2S1 | c.583G>A p.D195N | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as rs543776067, COSV59507121; called by muse, mutect2, varscan2
- CYP4A11 | c.431G>A p.R144Q | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.473); catalogued as rs148717576, COSV60222126; called by muse, mutect2, varscan2
- CYP4F8 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 26/133 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as COSV57855107; called by muse, mutect2, varscan2
- DAB1 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1196540942, COSV59734118, COSV59736943; called by muse, varscan2
- DAB1 | c.76C>T p.R26C | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); catalogued as COSV59725348; called by muse, varscan2
- DAGLA | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.971); catalogued as COSV57199578; called by muse, mutect2, varscan2
- DAGLA | c.2488G>A p.E830K | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.534); catalogued as COSV57196352; called by muse, mutect2, varscan2
- DAND5 | c.362G>A p.R121Q | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs748806881, COSV57684082; called by muse, mutect2, varscan2
- DAXX | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated (0.53); PolyPhen benign (0.044); catalogued as rs1469404232, COSV99802517; called by muse, mutect2, varscan2
- DCAF16 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 28/110 reads (25%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.092); catalogued as rs751989926, COSV66384389; called by muse, mutect2, varscan2
- DCC | c.2176C>T p.P726S | Missense Mutation (SNP) | VAF 20/24 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59092538; called by muse, varscan2
- DCDC1 | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as COSV60858087; called by muse, varscan2
- DCLK3 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as COSV69364687; called by muse, mutect2, varscan2
- DCTN4 | c.74C>T p.S25L | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV69783079; called by muse, varscan2
- DCTN4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV69783081; called by muse, varscan2
- DDX60 | c.4282C>T p.Q1428* | Nonsense Mutation (SNP) | VAF 16/22 reads (73%) | catalogued as COSV67099282; called by muse, mutect2, varscan2
- DDX60L | c.3800G>A p.G1267E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV52721661; called by muse, mutect2, varscan2
- DEPP1 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs746153313, COSV100024348, COSV53575124; called by muse, mutect2, varscan2
- DGKZ | c.2878C>T p.P960S (on ENST00000454345 / NM_001105540.2; = p.P772S on NM_003646.4) | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs761379422, COSV58994917; called by muse, mutect2, varscan2
- DHX40 | c.2011C>T p.H671Y | Missense Mutation (SNP) | VAF 38/55 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52067037, COSV52069968; called by muse, mutect2, varscan2
- DLG2 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV54625070, COSV99719151; called by muse, mutect2, varscan2
- DLG3 | c.458A>C p.H153P | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52087004; called by muse, mutect2, varscan2
- DLG4 | c.590G>A p.G197E (on ENST00000399506 / NM_001321075.3; = p.G240E on NM_001365.4) | Missense Mutation (SNP) | VAF 29/58 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV57242052; called by muse, mutect2, varscan2
- DLG5 | c.4954C>T p.P1652S | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64947397; called by muse, mutect2, varscan2
- DMBT1 | c.6319C>T p.R2107C (on ENST00000338354 / NM_001377530.1; = p.R1350C on NM_004406.3) | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs747972203, COSV57544508; called by muse, mutect2, varscan2
- DMBX1 | c.998G>A p.G333D | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.37); catalogued as rs776322510, COSV63602600; called by muse, mutect2, varscan2
- DMD | c.9184G>A p.E3062K | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); catalogued as COSV58952158; called by muse, mutect2, varscan2
- DMD | c.3435C>T p.V1145= | Splice Region (SNP) | VAF 5/18 reads (28%) | catalogued as COSV63790737; called by muse, mutect2, varscan2
- DMWD | c.1905C>T p.F635= | Splice Region (SNP) | VAF 24/109 reads (22%) | catalogued as COSV99353580; called by muse, mutect2, varscan2
- DMXL2 | c.5141C>T p.S1714F | Missense Mutation (SNP) | VAF 112/176 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as COSV51855939; called by muse, mutect2, varscan2
- DNAH1 | c.4043C>T p.A1348V | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as rs372583710; called by muse, mutect2, varscan2
- DNAH10 | c.13300G>A p.G4434R (on ENST00000409039; = p.G4373R on NM_207437.3) | Missense Mutation (SNP) | VAF 34/53 reads (64%) | SIFT tolerated (0.48); PolyPhen benign (0.022); catalogued as COSV53022168; called by muse, mutect2, varscan2
- DNAH3 | c.9137G>A p.G3046E | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54550630; called by muse, mutect2, varscan2
- DNAH5 | c.11212G>A p.E3738K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54205533, COSV99455398; called by mutect2, varscan2
- DNAH5 | c.2734G>A p.E912K | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV54208229; called by muse, mutect2, varscan2
- DNAH5 | c.1339C>T p.H447Y | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV99446950; called by muse, mutect2, varscan2
- DNAH8 | c.10334G>A p.G3445E | Missense Mutation (SNP) | VAF 100/115 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs371685174; called by muse, mutect2, varscan2
- DNAH8 | c.11502G>A p.W3834* | Nonsense Mutation (SNP) | VAF 104/135 reads (77%) | catalogued as COSV59479524; called by muse, mutect2, varscan2
- DNAH9 | c.4826C>T p.S1609F | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1176596556, COSV52339467; called by muse, mutect2, varscan2
- DNAH9 | c.7913G>A p.G2638E | Missense Mutation (SNP) | VAF 87/110 reads (79%) | SIFT tolerated (0.36); PolyPhen benign (0.012); catalogued as COSV52349017; called by muse, mutect2, varscan2
- DNAH9 | c.8876G>A p.G2959E | Missense Mutation (SNP) | VAF 72/91 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52350716; called by muse, mutect2, varscan2
- DNAI3 | c.1639C>T p.P547S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.527); catalogued as COSV54005975; called by muse, mutect2, varscan2
- DNAJB12 | c.1040T>A p.V347D (on ENST00000338820; = p.V313D on NM_017626.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV58761689; called by muse, mutect2, varscan2
- DNAJB8 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV59878969; called by muse, mutect2
- DNAJC17 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 54/81 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53067329; called by muse, mutect2, varscan2
- DNAJC6 | c.2732C>T p.P911L | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV54781511; called by muse, mutect2, varscan2
- DNASE1L3 | c.401C>T p.P134L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59157401; called by muse, mutect2, varscan2
- DOCK6 | c.4753A>G p.I1585V | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.417); catalogued as COSV53922308; called by mutect2, varscan2
- DONSON | c.407C>T p.S136L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV51679814; called by muse, mutect2
- DPYD | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as rs1284271720, COSV64614156; called by muse, mutect2, varscan2
- DSC1 | c.1156C>T p.P386S | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT tolerated (0.2); PolyPhen benign (0.371); catalogued as COSV57151331; called by muse, mutect2, varscan2
- DSG1 | c.1762G>A p.E588K | Missense Mutation (SNP) | VAF 36/48 reads (75%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.647); catalogued as rs200028630; called by muse, varscan2
- DSG1 | c.1783C>T p.H595Y | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV57136234; called by muse, varscan2
- DSG4 | c.403G>A p.E135K | Missense Mutation (SNP) | VAF 30/37 reads (81%) | SIFT tolerated (0.41); PolyPhen benign (0.18); catalogued as COSV57397473; called by muse, mutect2, varscan2
- DSG4 | c.2512C>T p.P838S | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.919); catalogued as COSV57397489; called by muse, mutect2, varscan2
- DSP | c.8582C>T p.S2861F | Missense Mutation (SNP) | VAF 123/151 reads (81%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.451); catalogued as rs1269834512, COSV60939123, COSV60941061; called by muse, mutect2, varscan2
- DYNC2H1 | c.3576C>T p.I1192= | Splice Region (SNP) | VAF 4/16 reads (25%) | catalogued as rs180790392; called by mutect2, varscan2
- EBF2 | c.719G>A p.G240E | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV68780541; called by muse, mutect2, varscan2
- EDARADD | c.232G>A p.G78S (on ENST00000334232 / NM_145861.4; = p.G68S on NM_080738.4) | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.185); catalogued as COSV62065081; called by muse, mutect2, varscan2
- EFCAB6 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 22/100 reads (22%) | SIFT tolerated (0.85); PolyPhen benign (0.006); catalogued as COSV53072381; called by muse, mutect2, varscan2
- EGFL6 | c.1053A>T p.K351N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.075); catalogued as COSV63635299; called by muse, mutect2, varscan2
- EGFLAM | c.413C>T p.S138F | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.042); catalogued as COSV59295169; called by muse, mutect2, varscan2
- EIF2AK4 | c.296C>G p.S99* | Nonsense Mutation (SNP) | VAF 35/63 reads (56%) | catalogued as COSV55474021; called by muse, mutect2, varscan2
- EIF2B3 | c.992C>A p.S331Y | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV64518707; called by muse, mutect2, varscan2
- ELAVL2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 53/69 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1563970615, COSV56359348; called by muse, mutect2, varscan2
- ELAVL4 | c.521G>A p.G174E | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63914355, COSV63919081; called by muse, mutect2, varscan2
- ELN | c.1620C>T p.L540= | Splice Region (SNP) | VAF 25/153 reads (16%) | catalogued as COSV52715408; called by muse, mutect2, varscan2
- EMILIN2 | c.1993C>T p.H665Y | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV54427454; called by muse, mutect2, varscan2
- EML1 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.011); catalogued as rs757227237, COSV51752471; called by muse, mutect2, varscan2
- ENOX1 | c.410G>A p.R137Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV54918113; called by muse, mutect2, varscan2
- ENPP3 | c.254T>C p.F85S | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV62956623; called by muse, mutect2, varscan2
- EPB41 | c.1559C>T p.A520V (on ENST00000343067 / NM_001166005.2; = p.A311V on NM_004437.4) | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV58054013; called by muse, mutect2, varscan2
- EPB41L1 | c.2173G>A p.D725N | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs532611675, COSV52444521; called by muse, mutect2, varscan2
- EPB41L4A | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.985); catalogued as rs759881837, COSV54880359; called by muse, mutect2
- EPC1 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as COSV53929690; called by muse, mutect2, varscan2
- EPHA5 | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.114); catalogued as COSV56673226, COSV56683765; called by muse, mutect2, varscan2
- EPHB2 | c.2881G>A p.A961T (on ENST00000400191 / NM_001309193.2; = p.A962T on NM_004442.7) | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.25); catalogued as COSV65866652; called by muse, varscan2
- EPHB6 | c.1607C>T p.S536F | Missense Mutation (SNP) | VAF 61/93 reads (66%) | SIFT tolerated (0.26); PolyPhen benign (0.105); catalogued as COSV63890233; called by muse, mutect2, varscan2
- ESRP1 | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 279/462 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64412625; called by muse, mutect2, varscan2
- ESX1 | c.587G>A p.R196Q | Missense Mutation (SNP) | VAF 64/220 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs144948361, COSV65424116; called by muse, mutect2, varscan2
- EXO1 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62219879; called by muse, mutect2, varscan2
- EXPH5 | c.526C>T p.H176Y | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as COSV56208055; called by mutect2, varscan2
- F8 | c.4247C>T p.P1416L | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.444); catalogued as rs1557278470, COSV64278548; called by muse, mutect2, varscan2
- F8 | c.3892G>A p.G1298S | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs1276607905, COSV64278556; called by muse, mutect2, varscan2
- F8 | c.2980G>A p.G994R | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV64278563; called by muse, mutect2, varscan2
- FAAH | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 44/85 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54545900; called by muse, mutect2, varscan2
- FAM120C | c.2918C>T p.S973F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.652); catalogued as COSV60262443; called by muse, mutect2, varscan2
- FAM131B | c.438G>A p.M146I | Missense Mutation (SNP) | VAF 89/121 reads (74%) | SIFT tolerated (0.14); PolyPhen benign (0.406); catalogued as COSV68125513; called by muse, mutect2, varscan2
- FAM13C | c.779C>T p.P260L | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV53255778; called by muse, mutect2, varscan2
- FAM151A | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV56363092; called by muse, mutect2, varscan2
- FAM153A | c.36G>A p.M12I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as rs1487861845, COSV100647104; called by mutect2, varscan2
- FAM241A | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0.019); catalogued as rs866555738, COSV59036448; called by muse, mutect2, varscan2
- FAM53C | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 42/77 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs766141980, COSV53512923; called by muse, mutect2, varscan2
- FAM83E | c.868C>T p.P290S | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV52378747; called by muse, mutect2, varscan2
- FAP | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV51863899; called by muse, mutect2, varscan2
- FAT3 | c.824C>T p.S275L | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT tolerated (0.33); PolyPhen benign (0.052); catalogued as rs574059534, COSV53167409, COSV53172293; called by muse, mutect2, varscan2
- FAT4 | c.10055A>G p.K3352R | Missense Mutation (SNP) | VAF 30/57 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0.06); catalogued as COSV58681601, COSV58686093; called by muse, mutect2, varscan2
- FAT4 | c.12508C>T p.R4170C | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.401); catalogued as rs540573222, COSV58698871; called by muse, mutect2, varscan2
- FAT4 | c.13597G>A p.G4533R | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.4); catalogued as rs999854092, COSV58708176; called by muse, mutect2, varscan2
- FAT4 | c.14708G>A p.G4903E | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs549460745, COSV58708195; called by muse, mutect2, varscan2
- FBLN1 | c.344T>C p.L115P | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53053885; called by muse, mutect2, varscan2
- FBXL13 | c.1538G>A p.R513Q | Missense Mutation (SNP) | VAF 55/79 reads (70%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.808); catalogued as rs760076024, COSV57534971; called by muse, mutect2, varscan2
- FBXO10 | c.1318G>A p.G440R | Missense Mutation (SNP) | VAF 42/47 reads (89%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1242900357, COSV52835528; called by muse, mutect2, varscan2
- FBXO24 | c.55C>T p.P19S (on ENST00000241071 / NM_033506.3; = p.P57S on NM_012172.5) | Missense Mutation (SNP) | VAF 99/150 reads (66%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.604); catalogued as COSV53829417; called by muse, mutect2, varscan2
- FBXO39 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 22/28 reads (79%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as COSV58623076; called by muse, mutect2, varscan2
- FCGBP | c.5869G>A p.E1957K | Missense Mutation (SNP) | VAF 36/418 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.891); catalogued as rs200124142, COSV55454291; called by muse, mutect2
- FER1L5 | c.4184G>A p.R1395K (on ENST00000623019; = p.R1368K on NM_001293083.2) | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV67607022; called by muse, mutect2, varscan2
- FER1L6 | c.2878C>A p.P960T | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.722); catalogued as rs773119344, COSV67552380, COSV67552764; called by muse, mutect2, varscan2
- FGD2 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 56/66 reads (85%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as rs752500567, COSV51466082; called by muse, mutect2, varscan2
- FGD5 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV53251848; called by muse, mutect2, varscan2
- FGFBP1 | c.556G>A p.V186M | Missense Mutation (SNP) | VAF 43/80 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.039); catalogued as COSV52587279; called by muse, mutect2, varscan2
- FGFR2 | c.2068G>A p.G690R | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1311258996, COSV100336630, COSV60659184; called by muse, mutect2, varscan2
- FHDC1 | c.2821C>G p.R941G | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV52602896, COSV99035930; called by muse, mutect2, varscan2
- FLG | c.2968G>A p.E990K | Missense Mutation (SNP) | VAF 100/192 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.017); catalogued as rs764938074, COSV64241010; called by muse, mutect2, varscan2
- FLNB | c.5992G>A p.E1998K | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55894908; called by muse, mutect2, varscan2
- FLNC | c.3844G>A p.A1282T | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT tolerated (0.31); PolyPhen benign (0.103); catalogued as COSV57964708; called by muse, mutect2, varscan2
- FLNC | c.4135G>A p.G1379S | Missense Mutation (SNP) | VAF 65/91 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57964719; called by muse, mutect2, varscan2
- FLNC | c.4217C>T p.T1406I | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV57961060, COSV57964729; called by muse, mutect2, varscan2
- FLT1 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV56742603; called by muse, mutect2, varscan2
- FLT3 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 40/75 reads (53%) | SIFT deleterious (0.03); PolyPhen benign (0.318); catalogued as COSV54057630; called by muse, mutect2, varscan2
- FMN2 | c.1297C>T p.P433S | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as COSV60452916; called by muse, mutect2, varscan2
- FMN2 | c.1987G>A p.E663K | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.244); catalogued as COSV60427033, COSV60437540; called by muse, mutect2, varscan2
- FMO1 | c.550G>A p.D184N | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as rs1407348271, COSV61447810; called by muse, mutect2, varscan2
- FMO3 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 29/47 reads (62%) | SIFT tolerated (0.14); PolyPhen benign (0.097); catalogued as rs866502499, COSV63006994; called by muse, mutect2, varscan2
- FMO4 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs759860288, COSV63001219; called by muse, mutect2, varscan2
- FMR1 | c.1372G>A p.E458K | Missense Mutation (SNP) | VAF 29/108 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.403); catalogued as COSV54427406; called by muse, varscan2
- FOXA2 | c.399G>A p.M133I (on ENST00000377115 / NM_153675.3; = p.M139I on NM_021784.5) | Missense Mutation (SNP) | VAF 44/107 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.484); catalogued as rs1000920736, COSV65797091; called by muse, mutect2, varscan2
- FRAS1 | c.6095A>T p.D2032V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53646283; called by muse, mutect2, varscan2
- FRAS1 | c.7820G>A p.G2607E | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as rs1440019543, COSV53646308; called by muse, mutect2, varscan2
- FREM1 | c.2491C>T p.P831S | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as rs1438943666, COSV66529989; called by muse, mutect2, varscan2
- FRMD4B | c.2312T>G p.V771G | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV101273639, COSV68331191; called by muse, mutect2, varscan2
- FRMD7 | c.131G>A p.G44E | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53748734; called by muse, mutect2, varscan2
- FRMPD2 | c.3802G>A p.E1268K | Missense Mutation (SNP) | VAF 23/40 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100564086; called by mutect2, varscan2
- FRMPD3 | c.763C>T p.H255Y | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV99346853; called by muse, mutect2, varscan2
- FRMPD4 | c.3278G>A p.W1093* | Nonsense Mutation (SNP) | VAF 24/112 reads (21%) | catalogued as COSV66223246; called by muse, mutect2, varscan2
- FRYL | c.214C>T p.P72S | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV51962045; called by muse, mutect2
- FSCN2 | c.341C>T p.T114I | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV58369270; called by muse, mutect2, varscan2
- FSIP2 | c.20473G>A p.E6825K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.402); catalogued as COSV58099308; called by muse, mutect2, varscan2
- FYCO1 | c.497C>T p.S166L | Missense Mutation (SNP) | VAF 33/62 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs1335395536, COSV56119474; called by muse, mutect2, varscan2
- GAB4 | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 166/229 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs867433638, COSV68752963; called by muse, mutect2, varscan2
- GABPB1 | c.276G>A p.K92= | Splice Region (SNP) | VAF 12/75 reads (16%) | catalogued as COSV55017538; called by muse, mutect2, varscan2
- GABRB2 | c.1118G>A p.R373Q | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs202183786, COSV50936354; ClinVar: benign; called by muse, mutect2, varscan2
- GABRG1 | c.1277C>T p.S426F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as COSV54951926, COSV54961565; called by muse, mutect2
- GALNT15 | c.1267G>A p.D423N | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV60217706, COSV60218833; called by muse, mutect2, varscan2
- GALP | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV62001139; called by muse, mutect2, varscan2
- GAS2L1 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); catalogued as rs1255845287, COSV53331917; called by muse, mutect2, varscan2
- GATD1 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as COSV60593534; called by muse, mutect2
- GBF1 | c.3644A>T p.E1215V (on ENST00000369983 / NM_001377137.1; = p.E1214V on NM_004193.3) | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV64148941; called by muse, mutect2
- GCKR | c.1834C>A p.R612S | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.838); catalogued as CM120213, COSV53110977; called by muse, mutect2, varscan2
- GCNT1 | c.64C>T p.L22F | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT tolerated (0.28); PolyPhen benign (0.255); catalogued as rs868834520, COSV65058801; called by muse, mutect2, varscan2
- GCSAML | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.563); catalogued as COSV63579529; called by muse, varscan2
- GDF3 | c.518C>T p.P173L | Missense Mutation (SNP) | VAF 51/65 reads (78%) | SIFT tolerated (0.08); PolyPhen benign (0.055); catalogued as COSV61713676; called by muse, mutect2, varscan2
- GDPD4 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.031); catalogued as rs757541625, COSV60017170; called by muse, mutect2, varscan2
- GHRH | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 93/269 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as rs766281633, COSV52903114; called by muse, mutect2, varscan2
- GIMAP5 | c.8G>A p.G3E | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.213); catalogued as COSV62280684; called by muse, mutect2, varscan2
- GK2 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 18/71 reads (25%) | catalogued as COSV62628374; called by muse, mutect2, varscan2
- GLCCI1 | c.1294A>C p.M432L | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV56205180; called by muse, mutect2, varscan2
- GLI3 | c.3095C>T p.P1032L | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.024); catalogued as COSV67894743; called by muse, mutect2
- GLRB | c.1198-1G>A p.X400_splice | Splice Site (SNP) | VAF 10/20 reads (50%) | catalogued as rs754290626, COSV52422409; called by muse, mutect2, varscan2
- GNAI2 | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 29/50 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56493295; called by muse, mutect2, varscan2
- GNB4 | c.455T>C p.L152S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as COSV51711825; called by muse, mutect2, varscan2
- GOLGA4 | c.6340C>T p.Q2114* | Nonsense Mutation (SNP) | VAF 12/26 reads (46%) | catalogued as COSV100729091; called by muse, mutect2, varscan2
- GP6 | c.962C>T p.S321L | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.081); catalogued as COSV59979632; called by muse, mutect2, varscan2
- GPATCH1 | c.770T>C p.L257P | Missense Mutation (SNP) | VAF 27/111 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV50126248; called by muse, mutect2, varscan2
- GPC5 | c.823C>T p.L275F | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV65629057; called by muse, mutect2, varscan2
- GPR12 | c.547C>T p.R183* | Nonsense Mutation (SNP) | VAF 11/38 reads (29%) | catalogued as COSV67344910; called by muse, mutect2, varscan2
- GPR139 | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV58501661; called by muse, mutect2, varscan2
- GPR83 | c.991C>T p.H331Y | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54720725; called by muse, mutect2, varscan2
- GPRASP1 | c.2059C>T p.P687S | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.023); catalogued as COSV64356451; called by muse, mutect2, varscan2
- GPRC6A | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.284); catalogued as rs1562481852, COSV59955869; called by muse, mutect2, varscan2
- GPX5 | c.543G>A p.W181* | Nonsense Mutation (SNP) | VAF 93/105 reads (89%) | catalogued as rs1316053885, COSV69079836; called by muse, mutect2, varscan2
- GRIA1 | c.1826C>T p.S609F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53623977; called by muse, mutect2, varscan2
- GRIA2 | c.2368G>A p.D790N | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371939918; called by muse, mutect2, varscan2
- GRIA3 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV52079805; called by muse, mutect2, varscan2
- GRID1 | c.2601G>A p.E867= | Splice Region (SNP) | VAF 8/32 reads (25%) | catalogued as COSV60052350; called by muse, mutect2, varscan2
- GRID2 | c.1939T>A p.S647T | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as COSV56264247; called by muse, mutect2, varscan2
- GRIK4 | c.2167G>A p.E723K | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70802350; called by muse, mutect2, varscan2
- GRIN2B | c.829C>T p.L277F | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV74205963; called by muse, mutect2, varscan2
- GRIPAP1 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.405); catalogued as rs1557065200, COSV64553400; called by muse, mutect2, varscan2
- GRM5 | c.1576G>T p.G526* | Nonsense Mutation (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100553736, COSV59597712; called by muse, varscan2
- GRXCR1 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.534); catalogued as COSV67669790; called by muse, mutect2, varscan2
- GRXCR1 | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 18/97 reads (19%) | catalogued as rs773562995, CM165102, COSV67672429; called by muse, mutect2, varscan2
- GRXCR2 | c.336+2T>C p.X112_splice | Splice Site (SNP) | VAF 5/31 reads (16%) | catalogued as COSV100940011; called by muse, mutect2
- GRXCR2 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV65061869; called by muse, mutect2, varscan2
- GTF2E2 | c.580C>T p.R194C | Missense Mutation (SNP) | VAF 35/65 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.19); catalogued as rs749607324, COSV63478237; called by muse, mutect2, varscan2
- GTF3C1 | c.4300C>T p.Q1434* | Nonsense Mutation (SNP) | VAF 21/53 reads (40%) | catalogued as COSV62244843; called by muse, mutect2, varscan2
- GTF3C2 | c.1927C>T p.L643F | Missense Mutation (SNP) | VAF 135/352 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53128724; called by muse, mutect2, varscan2
- GTPBP3 | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50198603; called by muse, mutect2
- GUCY1A1 | c.932G>A p.R311K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV56656413, COSV99638619; called by muse, mutect2, varscan2
- H1-4 | c.370G>A p.G124S | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV99175337; called by muse, mutect2, varscan2
- H1-4 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV56804276, COSV99175241; called by muse, mutect2, varscan2
- HBD | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.25); catalogued as rs747164859, CM130417, COSV53083595; called by muse, mutect2, varscan2
- HCAR1 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 17/23 reads (74%) | SIFT tolerated (0.21); PolyPhen benign (0.269); catalogued as COSV100811826, COSV63677838; called by muse, mutect2, varscan2
- HCN1 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.57); PolyPhen benign (0.223); catalogued as COSV57536540; called by muse, mutect2, varscan2
- HDAC8 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.116); catalogued as COSV65239985; called by muse, mutect2, varscan2
- HDGFL3 | c.190C>T p.P64S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV55207500; called by muse, mutect2, varscan2
- HEATR5A | c.2891C>T p.S964L | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as COSV66345513; called by muse, mutect2, varscan2
- HERC2 | c.2365C>T p.P789S | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.508); catalogued as COSV55349970; called by muse, mutect2, varscan2
- HMBOX1 | c.724C>T p.P242S | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs1364627014, COSV55071977; called by muse, varscan2
- HNRNPUL2 | c.2005G>A p.D669N | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.768); catalogued as rs755246; called by muse, mutect2, varscan2
- HPN | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV52886032; called by muse, mutect2, varscan2
- HRG | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.099); catalogued as COSV51648217; called by muse, mutect2
- HS3ST1 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 43/69 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50026550; called by muse, mutect2, varscan2
- HS3ST1 | c.713C>T p.S238L | Missense Mutation (SNP) | VAF 17/33 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.198); catalogued as COSV50026581; called by muse, mutect2, varscan2
- HSPG2 | c.2323C>T p.P775S | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65977141; called by muse, mutect2, varscan2
- HTATSF1 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV54481234; called by muse, mutect2, varscan2
- HTN1 | c.44C>T p.S15F | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.918); catalogued as COSV55895396; called by muse, mutect2
- HTR1F | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60391164; called by muse, mutect2, varscan2
- HTR1F | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.33); PolyPhen benign (0.245); catalogued as COSV60391174; called by muse, mutect2, varscan2
- HTR2C | c.1007T>A p.L336H | Missense Mutation (SNP) | VAF 38/82 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52224438; called by muse, mutect2, varscan2
- HTRA3 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.206); catalogued as COSV56473296; called by muse, mutect2, varscan2
- HTT | c.3323C>T p.S1108L | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.205); catalogued as COSV61869041; called by muse, mutect2, varscan2
- HUNK | c.952C>T p.R318C | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs192440238, COSV54234259; called by muse, mutect2, varscan2
- HUWE1 | c.3907G>A p.D1303N | Missense Mutation (SNP) | VAF 28/104 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs782804715, COSV53363562; called by muse, mutect2, varscan2
- IARS2 | c.1390C>T p.P464S | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56962095; called by muse, mutect2, varscan2
- IARS2 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1462178478, COSV100228542; called by muse, mutect2, varscan2
- IFI44L | c.683A>T p.Q228L | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1290849843, COSV60729389; called by muse, mutect2, varscan2
- IFT80 | c.924T>A p.F308L | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV58452343; called by muse, mutect2, varscan2
- IGHD | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.81); catalogued as COSV101162994; called by muse, mutect2, varscan2
- IGSF10 | c.967C>T p.Q323* | Nonsense Mutation (SNP) | VAF 16/78 reads (21%) | catalogued as COSV56791484; called by muse, mutect2, varscan2
- IL16 | c.2600C>T p.S867F (on ENST00000302987 / NM_172217.5; = p.S166F on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57268039; called by muse, mutect2
- IL18 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs199505901, COSV54780968; called by mutect2, varscan2
- IL20 | c.128G>A p.R43Q | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.013); catalogued as rs750758066, COSV65584312; called by muse, mutect2, varscan2
- IL2RA | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV56920470, COSV99906853; called by muse, mutect2, varscan2
- IL5RA | c.149G>A p.W50* | Nonsense Mutation (SNP) | VAF 19/28 reads (68%) | catalogued as COSV56526343, COSV99842741; called by muse, mutect2, varscan2
- ILDR1 | c.1132C>T p.Q378* (on ENST00000344209 / NM_001199799.2; = p.Q334* on NM_175924.4) | Nonsense Mutation (SNP) | VAF 37/70 reads (53%) | catalogued as COSV56553798; called by muse, mutect2, varscan2
- IMPG1 | c.2206G>A p.E736K | Missense Mutation (SNP) | VAF 63/73 reads (86%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV63113297; called by muse, mutect2, varscan2
- INPP5F | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.689); catalogued as COSV62823765; called by muse, mutect2, varscan2
- INPPL1 | c.2786C>T p.S929F | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.496); catalogued as COSV99996525; called by muse, mutect2, varscan2
- INSL6 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 68/88 reads (77%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs767708471, COSV67563467; called by muse, varscan2
- INTS14 | c.322C>T p.P108S (on ENST00000313182 / NM_001366360.2; = p.P29S on NM_001136043.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.958); catalogued as COSV57528843; called by muse, mutect2, varscan2
- INTS8 | c.1825C>T p.Q609* | Nonsense Mutation (SNP) | VAF 419/668 reads (63%) | catalogued as COSV58253300; called by muse, mutect2, varscan2
- IPO5 | c.2846C>T p.P949L | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV55159734; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1247C>T p.S416F (on ENST00000485419 / NM_001197113.1; = p.S340F on NM_014575.3) | Missense Mutation (SNP) | VAF 103/192 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61858948; called by muse, mutect2, varscan2
- ITGA1 | c.350C>T p.S117L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV50897544; called by muse, mutect2, varscan2
- ITGA8 | c.2572C>T p.H858Y | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.811); catalogued as COSV65235711; called by muse, mutect2, varscan2
- ITGB1 | c.2378C>T p.P793L | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56486796; called by muse, mutect2, varscan2
- ITIH2 | c.738+1G>A p.X246_splice | Splice Site (SNP) | VAF 12/57 reads (21%) | catalogued as COSV64435188; called by muse, mutect2, varscan2
- ITIH6 | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.853); catalogued as COSV54494461, COSV99513765; called by muse, mutect2, varscan2
- ITK | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 149/273 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs752554340, COSV70065117; called by muse, mutect2, varscan2
- ITPKB | c.713C>T p.P238L | Missense Mutation (SNP) | VAF 42/173 reads (24%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as rs761742131, COSV55269710; called by muse, mutect2, varscan2
- ITPRID2 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57470227; called by muse, mutect2, varscan2
- JCAD | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 58/103 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV64761610; called by muse, mutect2, varscan2
- JCAD | c.1396G>A p.G466R | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.078); catalogued as rs868074715, COSV64760532; called by muse, mutect2, varscan2
- JHY | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.873); catalogued as COSV56221757; called by muse, mutect2, varscan2
- KALRN | c.76C>T p.R26W | Missense Mutation (SNP) | VAF 39/149 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV53755097, COSV99563522; called by muse, mutect2, varscan2
- KALRN | c.553G>A p.E185K | Missense Mutation (SNP) | VAF 29/48 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs546138856, COSV53765041; called by muse, mutect2, varscan2
- KALRN | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.992); catalogued as rs1560594705, COSV53780017; called by muse, mutect2, varscan2
- KALRN | c.3927G>A p.W1309* | Nonsense Mutation (SNP) | VAF 8/41 reads (20%) | catalogued as COSV53780031; called by muse, mutect2, varscan2
- KALRN | c.4588G>A p.E1530K | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53780049; called by muse, mutect2, varscan2
- KAT2B | c.1657C>G p.R553G | Missense Mutation (SNP) | VAF 16/92 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55434452; called by muse, mutect2, varscan2
- KATNAL2 | c.250C>T p.Q84* (on ENST00000356157 / NM_001353899.1; = p.Q12* on NM_031303.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 43/58 reads (74%) | catalogued as COSV55299813; called by muse, mutect2, varscan2
- KBTBD3 | c.1496C>A p.A499E | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781581063, COSV73241634; called by muse, mutect2, varscan2
- KBTBD8 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | catalogued as rs772528470, COSV55131362; called by muse, mutect2, varscan2
- KCNA5 | c.1645G>A p.D549N | Missense Mutation (SNP) | VAF 44/52 reads (85%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV52908649; called by muse, mutect2, varscan2
- KCNAB1 | c.386A>G p.Y129C (on ENST00000490337 / NM_172160.3; = p.Y118C on NM_003471.3) | Missense Mutation (SNP) | VAF 69/112 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765185391, COSV100205303, COSV56753710; called by muse, mutect2, varscan2
- KCNB2 | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.957); catalogued as rs758944083, COSV73051961; called by muse, mutect2, varscan2
- KCNH7 | c.2698G>A p.E900K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs1422326185, COSV59793322; called by muse, mutect2, varscan2
- KCNK13 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 37/106 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56410433; called by muse, mutect2, varscan2
- KCNK3 | c.1043G>A p.G348E | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV57194640; called by muse, mutect2, varscan2
- KCNK9 | c.1104G>A p.M368I | Missense Mutation (SNP) | VAF 77/131 reads (59%) | SIFT tolerated (0.35); PolyPhen benign (0.033); catalogued as COSV57288249; called by muse, mutect2, varscan2
- KCNT2 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs370788660; called by muse, mutect2
- KDM2B | c.2924C>T p.S975L | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.101); catalogued as rs781789924, COSV65645056; called by muse, mutect2, varscan2
- KDM3B | c.1906C>T p.P636S | Missense Mutation (SNP) | VAF 23/80 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.113); catalogued as COSV58695182; called by muse, mutect2, varscan2
- KDR | c.2494G>A p.D832N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs768465015, COSV55757880, COSV55775792, COSV99028776; called by mutect2, varscan2
- KIAA1109 | c.6127C>T p.P2043S | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52691631; called by muse, mutect2, varscan2
- KIAA1109 | c.11236T>C p.Y3746H | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.991); catalogued as COSV52691647; called by muse, mutect2, varscan2
- KIAA1210 | c.4846G>A p.E1616K | Missense Mutation (SNP) | VAF 70/135 reads (52%) | SIFT tolerated (0.92); PolyPhen benign (0.062); catalogued as COSV68177228; called by muse, mutect2, varscan2
- KIF1C | c.2711C>T p.P904L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.026); catalogued as COSV57907315; called by muse, mutect2, varscan2
- KIF26B | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.544); catalogued as COSV69471814, COSV69473393; called by muse, mutect2
- KIFC1 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 50/57 reads (88%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV100997129; called by muse, mutect2, varscan2
- KIR2DL1 | c.719A>G p.N240S | Missense Mutation (SNP) | VAF 20/146 reads (14%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV99382642, COSV99383657; called by muse, varscan2
- KLHL13 | c.1211G>A p.G404E | Missense Mutation (SNP) | VAF 28/45 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs867961131, COSV53250888; called by muse, mutect2, varscan2
- KLK5 | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60451559; called by muse, mutect2, varscan2
- KLK7 | c.665G>A p.G222E | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58344993; called by muse, mutect2
- KLRC3 | c.550C>T p.P184S | Missense Mutation (SNP) | VAF 28/29 reads (97%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs534396424, COSV67251510; called by muse, mutect2, varscan2
- KRT78 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58853739; called by muse, mutect2
- KRTAP19-5 | c.142T>C p.S48P | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.072); catalogued as COSV61859588; called by muse, mutect2, varscan2
- KSR2 | c.2596G>A p.E866K | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV56683122; called by muse, mutect2, varscan2
- LAIR1 | c.49C>A p.Q17K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.452); catalogued as COSV57309843; called by muse, mutect2, varscan2
- LAMA1 | c.6781C>T p.P2261S | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.22); PolyPhen benign (0.441); catalogued as COSV67536934, COSV67544239; called by muse, mutect2, varscan2
- LAMB4 | c.1328G>A p.G443E | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV52730810; called by muse, mutect2, varscan2
- LAMP3 | c.611C>T p.T204I | Missense Mutation (SNP) | VAF 90/142 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs755635197, COSV55616968; called by muse, mutect2, varscan2
- LCT | c.5294G>A p.R1765K | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV51557337; called by muse, mutect2, varscan2
- LEXM | c.1176G>C p.M392I | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV64024148; called by muse, mutect2, varscan2
- LIG3 | c.35C>T p.T12I | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV52011232; called by muse, mutect2, varscan2
- LILRB4 | c.739G>T p.G247W | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.055); catalogued as COSV54406547, COSV54408551; called by muse, mutect2, varscan2
- LIPC | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.07); PolyPhen benign (0.316); catalogued as rs372553692; called by muse, mutect2, varscan2
- LMOD3 | c.1282C>T p.P428S | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.941); catalogued as rs1397712222, COSV101342019; called by muse, mutect2, varscan2
- LRCH2 | c.2183G>A p.R728K | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV57757362; called by muse, mutect2
- LRFN5 | c.862C>T p.L288F | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV53258897, COSV53269538, COSV99984233; called by muse, mutect2, varscan2
- LRIG3 | c.2177C>T p.P726L | Missense Mutation (SNP) | VAF 43/52 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57860820, COSV57869770; called by muse, mutect2, varscan2
- LRP10 | c.1699C>T p.P567S | Missense Mutation (SNP) | VAF 44/79 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62078341; called by muse, mutect2, varscan2
- LRP12 | c.1741G>T p.A581S | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV52634467; called by muse, mutect2, varscan2
- LRP1B | c.4834G>A p.D1612N | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67273410; called by muse, mutect2, varscan2
- LRP2 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV55573620; called by muse, mutect2, varscan2
- LRP8 | c.2327A>C p.E776A | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV60101252; called by muse, mutect2, varscan2
- LRRC6 | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV51547469; called by muse, mutect2
- LRRK2 | c.864A>T p.L288F | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as COSV54170103; called by muse, mutect2, varscan2
- LYSMD3 | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs200894296, COSV100270514; called by muse, mutect2, varscan2
- MACF1 | c.9163C>T p.P3055S | Missense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as COSV99246165; called by muse, mutect2, varscan2
- MACF1 | c.9164C>T p.P3055L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | catalogued as rs1456618937, COSV99246167; called by muse, mutect2, varscan2
- MAGEA12 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.198); catalogued as COSV63295451; called by muse, mutect2, varscan2
- MAGEA6 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV61449455; called by muse, mutect2, varscan2
- MAGEB1 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV66775504; called by muse, mutect2, varscan2
- MAGEB2 | c.457C>T p.L153F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.539); catalogued as COSV66781736; called by muse, mutect2, varscan2
- MAGEB6B | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 45/77 reads (58%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.965); catalogued as rs1409156461; called by muse, mutect2, varscan2
- MAGEC2 | c.28C>T p.R10C | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as rs774322661, COSV55997548; called by muse, mutect2, varscan2
- MAGEC3 | c.583C>T p.L195F | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as COSV71610242; called by muse, mutect2, varscan2
- MAGEH1 | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.456); catalogued as rs761395815, COSV61679239; called by muse, mutect2, varscan2
- MAP1B | c.6955G>A p.E2319K | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.045); catalogued as COSV57106217; called by muse, mutect2, varscan2
- MAP3K15 | c.3835G>A p.D1279N | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58838389; called by muse, mutect2, varscan2
- MAP3K15 | c.2480G>A p.G827E | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); catalogued as COSV58838414; called by muse, mutect2, varscan2
- MAPK15 | c.1408C>T p.R470W | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs536928468, COSV62030150; called by muse, mutect2, varscan2
- MARCHF7 | c.259C>T p.H87Y | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV52031336; called by muse, mutect2, varscan2
- MARCO | c.1403G>A p.G468E | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV59058507; called by muse, mutect2, varscan2
- MARK1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as rs749268082, COSV65071284; called by muse, mutect2, varscan2
- MAST1 | c.877G>A p.E293K | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV52254725; called by muse, mutect2, varscan2
- MAST4 | c.923C>T p.S308F (on ENST00000403625 / NM_001164664.2; = p.S119F on NM_015183.3) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55141458; called by muse, mutect2, varscan2
- MDC1 | c.5459C>T p.S1820L | Missense Mutation (SNP) | VAF 137/170 reads (81%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV64526726; called by muse, mutect2, varscan2
- MDGA1 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 80/95 reads (84%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.446); catalogued as rs768428298, COSV51801663; called by muse, mutect2, varscan2
- MECOM | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs761171278, COSV72110504; called by muse, mutect2, varscan2
- MED12L | c.2062G>A p.E688K | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.245); catalogued as COSV56369734; called by muse, mutect2, varscan2
- MET | c.3031C>T p.Q1011* | Nonsense Mutation (SNP) | VAF 11/61 reads (18%) | catalogued as COSV59268848; called by muse, mutect2, varscan2
- METTL21A | c.118C>G p.L40V | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV55882116; called by muse, mutect2, varscan2
- MFRP | c.440T>G p.L147R (on ENST00000449574; = p.L523R on NM_031433.4) | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV60991475; called by muse, mutect2, varscan2
- MGAM | c.3211C>T p.P1071S | Missense Mutation (SNP) | VAF 60/112 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.578); catalogued as COSV101527688; called by muse, mutect2, varscan2
- MGAM | c.3212C>T p.P1071L | Missense Mutation (SNP) | VAF 59/110 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV101527690, COSV72075232; called by muse, mutect2, varscan2
- MGAM | c.4540C>T p.P1514S | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV72073539; called by muse, mutect2, varscan2
- MGAM | c.4541C>T p.P1514L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs777555213, COSV72073882; called by muse, mutect2, varscan2
- MGAT3 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 98/160 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as rs1408868361, COSV57868399; called by muse, mutect2, varscan2
- MGST2 | c.77T>C p.V26A | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55498642; called by muse, mutect2, varscan2
- MLH1 | c.1040C>T p.T347I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV51624357; called by muse, mutect2, varscan2
- MMAB | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.122); catalogued as rs138708209; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMRN2 | c.1371G>A p.M457I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.01); catalogued as COSV64401376; called by muse, mutect2, varscan2
- MORC1 | c.1829C>T p.S610L | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV51725110, COSV51730899; called by muse, mutect2, varscan2
- MORF4L2 | c.119G>A p.G40E | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.77); catalogued as COSV64611408; called by muse, mutect2, varscan2
- MPPED1 | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 71/92 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV61988730; called by muse, mutect2, varscan2
- MPZ | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60669287; called by muse, mutect2, varscan2
- MRGPRX1 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as rs1050560364, COSV57109029; called by muse, mutect2, varscan2
- MROH2B | c.4432C>T p.Q1478* | Nonsense Mutation (SNP) | VAF 22/54 reads (41%) | catalogued as COSV68189368; called by muse, mutect2, varscan2
- MROH2B | c.3295G>A p.D1099N | Missense Mutation (SNP) | VAF 33/108 reads (31%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.946); catalogued as COSV68186415; called by muse, mutect2, varscan2
- MROH2B | c.3049G>A p.E1017K | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as rs374924519; called by muse, mutect2, varscan2
- MROH2B | c.582G>A p.M194I | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.961); catalogued as rs771053680, COSV68183965; called by muse, mutect2, varscan2
- MRTFA | c.2402C>T p.S801F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.308); catalogued as COSV62936733; called by muse, mutect2, varscan2
- MTRES1 | c.242C>T p.S81F | Missense Mutation (SNP) | VAF 81/95 reads (85%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV60968822; called by muse, mutect2, varscan2
- MTUS2 | c.2266C>T p.P756S | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV70922428; called by muse, mutect2, varscan2
- MUC13 | c.1061A>G p.N354S | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV60698715, COSV60701235; called by muse, mutect2, varscan2
- MUC16 | c.22366G>A p.V7456I | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.011); catalogued as COSV67492475; called by muse, mutect2, varscan2
- MUC16 | c.17756C>T p.P5919L | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV67492483; called by muse, mutect2, varscan2
- MUC16 | c.15979C>T p.P5327S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); catalogued as COSV67492490; called by mutect2, varscan2
- MUC16 | c.14974G>A p.D4992N | Missense Mutation (SNP) | VAF 21/40 reads (53%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.093); catalogued as COSV67492491; called by muse, mutect2, varscan2
- MUC16 | c.14602G>A p.E4868K | Missense Mutation (SNP) | VAF 60/105 reads (57%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.205); catalogued as COSV67484099; called by muse, mutect2, varscan2
- MUC16 | c.11062C>T p.P3688S | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.026); catalogued as rs1465360495, COSV67492492; called by muse, mutect2, varscan2
- MUC16 | c.5093G>A p.G1698E | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.197); catalogued as rs202026779, COSV67481448; called by muse, mutect2, varscan2
- MUC16 | c.2974C>G p.L992V | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV67492496; called by muse, varscan2
- MUC17 | c.1933G>A p.E645K | Missense Mutation (SNP) | VAF 183/253 reads (72%) | SIFT deleterious (0.03); PolyPhen benign (0.092); catalogued as rs757841353, COSV100071059, COSV60287714; called by muse, mutect2, varscan2
- MUC17 | c.8501C>T p.P2834L | Missense Mutation (SNP) | VAF 159/274 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs944117277, COSV60302857; called by muse, mutect2, varscan2
- MUC4 | c.13378C>T p.P4460S (on ENST00000463781 / NM_018406.7; = p.P224S on NM_004532.6) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV57789476; called by muse, mutect2
- MUC4 | c.2459G>A p.G820E | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.934); catalogued as COSV62134219; called by muse, mutect2, varscan2
- MUC5AC | c.14321C>T p.S4774F | Missense Mutation (SNP) | VAF 70/185 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs751325319, COSV100611559; called by muse, mutect2, varscan2
- MUC5B | c.11120G>A p.G3707E | Missense Mutation (SNP) | VAF 45/115 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV71595430; called by muse, mutect2, varscan2
- MVP | c.49C>T p.H17Y | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62422022; called by muse, mutect2, varscan2
- MXRA5 | c.6016G>A p.E2006K | Missense Mutation (SNP) | VAF 32/58 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV54230410; called by muse, mutect2, varscan2
- MXRA5 | c.4099G>A p.E1367K | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV54249955; called by muse, mutect2, varscan2
- MXRA5 | c.3259G>A p.G1087S | Missense Mutation (SNP) | VAF 41/53 reads (77%) | SIFT tolerated (0.26); PolyPhen benign (0.039); catalogued as COSV54249982; called by muse, mutect2, varscan2
- MYCBP2 | c.5116C>T p.P1706S (on ENST00000357337; = p.P1744S on NM_015057.5) | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.294); catalogued as COSV62038632; called by muse, mutect2, varscan2
- MYH4 | c.3151G>A p.D1051N | Missense Mutation (SNP) | VAF 64/82 reads (78%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.928); catalogued as COSV55125914; called by muse, mutect2, varscan2
- MYLK | c.3852G>A p.M1284I | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60622277; called by muse, mutect2, varscan2
- MYO1B | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1370367391, COSV58437743; called by muse, mutect2, varscan2
- MYO5C | c.4484G>A p.R1495Q | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs539722733, COSV55906722; called by muse, mutect2, varscan2
- MYO7B | c.4934C>T p.S1645F | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67351907; called by muse, mutect2, varscan2
- MYT1L | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV67706185, COSV67732262; called by muse, mutect2, varscan2
- MYT1L | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 33/58 reads (57%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs1188716845, COSV67728939; called by muse, mutect2, varscan2
- N4BP2 | c.2249C>T p.S750F | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV54706807; called by muse, mutect2, varscan2
- NAIP | c.172C>T p.R58C | Missense Mutation (SNP) | VAF 37/187 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs745325912, COSV52000932; called by muse, mutect2, varscan2
- NAPRT | c.1295C>T p.S432F | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as rs1374137247, COSV52788807; called by muse, mutect2, varscan2
- NBEA | c.301G>A p.G101S | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59821978; called by muse, mutect2, varscan2
- NCAPD2 | c.2755C>T p.P919S | Missense Mutation (SNP) | VAF 40/71 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.124); catalogued as COSV59702460; called by muse, mutect2, varscan2
- NCBP2L | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 18/33 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100966513; called by muse, mutect2, varscan2
- NCOA3 | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 25/86 reads (29%) | catalogued as COSV59071682, COSV59073327; called by muse, mutect2, varscan2
- NCOR2 | c.59C>T p.P20L | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.155); catalogued as rs757710006, COSV100657362, COSV100657371; called by muse, mutect2, varscan2
- NCOR2 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.943); catalogued as rs1171302955, COSV100657745; called by muse, mutect2, varscan2
- NDUFS5 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs751084864, COSV65892527; called by muse, mutect2, varscan2
- NEB | c.14623G>A p.D4875N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs1195616510, COSV51459232; called by muse, mutect2
- NEFM | c.2470G>A p.E824K | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.588); catalogued as rs762539334, COSV55334904; called by muse, mutect2, varscan2
- NES | c.4022G>A p.G1341D | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs770534305, COSV63962904; called by muse, mutect2, varscan2
- NES | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.012); catalogued as COSV63962907; called by muse, mutect2, varscan2
- NETO1 | c.131G>A p.W44* | Nonsense Mutation (SNP) | VAF 15/29 reads (52%) | catalogued as COSV55003147; called by muse, mutect2, varscan2
- NEXMIF | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.039); catalogued as COSV50102220; called by muse, mutect2, varscan2
- NFIC | c.197C>T p.P66L | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.073); catalogued as COSV59412934; called by muse, mutect2, varscan2
- NLGN3 | c.622G>A p.G208R (on ENST00000358741 / NM_181303.2; = p.G188R on NM_018977.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62445179; called by muse, varscan2
- NLGN4X | c.1360G>A p.V454M | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs199525017, COSV52022976, COSV52026711; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLGN4X | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.518); catalogued as rs1412018300, COSV52035862; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NLRP2 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 44/77 reads (57%) | SIFT tolerated (0.58); PolyPhen benign (0.052); catalogued as rs777322338, COSV54752788; called by muse, mutect2, varscan2
- NLRP2 | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1336047402, COSV54760196; called by muse, mutect2, varscan2
- NLRP4 | c.2920G>A p.E974K | Missense Mutation (SNP) | VAF 20/26 reads (77%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV56722934; called by muse, mutect2, varscan2
- NLRP8 | c.324G>A p.M108I | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV52590664, COSV52593577; called by muse, mutect2, varscan2
- NME8 | c.651G>A p.M217I | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1474558229, COSV52255259; called by muse, mutect2, varscan2
- NMS | c.25C>T p.P9S | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV100966643, COSV65259288; called by muse, mutect2, varscan2
- NMUR2 | c.514G>A p.G172S | Missense Mutation (SNP) | VAF 19/71 reads (27%) | SIFT tolerated (0.49); PolyPhen benign (0.012); catalogued as rs770057944; called by muse, mutect2
- NOBOX | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.015); catalogued as rs867952672, COSV56197673; called by muse, mutect2, varscan2
- NOVA1 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 45/127 reads (35%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.971); catalogued as COSV57487443; called by muse, mutect2, varscan2
- NPHS1 | c.3580G>A p.D1194N | Missense Mutation (SNP) | VAF 60/93 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.313); catalogued as rs890195712, COSV62286454; called by muse, mutect2, varscan2
- NPHS1 | c.3314C>T p.S1105L | Missense Mutation (SNP) | VAF 51/80 reads (64%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs552917975, COSV62289834; called by muse, mutect2, varscan2
- NPHS1 | c.2299C>T p.P767S | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773135022, CM153456, COSV62289839; called by muse, mutect2, varscan2
- NPSR1 | c.1067G>A p.R356K | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs1442234540, COSV62207611; called by muse, mutect2, varscan2
- NPTX1 | c.334G>A p.G112S | Missense Mutation (SNP) | VAF 70/105 reads (67%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1213809243, COSV60776456; called by muse, mutect2, varscan2
- NPY2R | c.707C>T p.S236L | Missense Mutation (SNP) | VAF 36/66 reads (55%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.765); catalogued as COSV61528479; called by muse, varscan2
- NPY2R | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV100279853, COSV61528577; called by muse, varscan2
- NRG2 | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs947701574, COSV56838133; called by muse, mutect2, varscan2
- NRIP3 | c.319A>T p.M107L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58471210; called by muse, mutect2, varscan2
- NRP2 | c.2470G>A p.G824R (on ENST00000360409 / NM_201266.2; = p.G819R on NM_003872.3) | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV63377909; called by muse, mutect2, varscan2
- NSD1 | c.6389T>C p.L2130P | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100729702; called by muse, mutect2, varscan2
- NSUN6 | c.1055G>A p.R352Q | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs200356504, COSV66035311; called by mutect2, varscan2
- NTAQ1 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs145997552, COSV54875872; called by muse, mutect2, varscan2
- NTSR1 | c.226G>A p.V76M | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100980689; called by muse, mutect2, varscan2
- NUDT7 | c.295C>T p.L99F | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs201253215, COSV51747112; called by muse, mutect2, varscan2
- NUF2 | c.607-1G>A p.X203_splice | Splice Site (SNP) | VAF 32/75 reads (43%) | catalogued as COSV54847112, COSV54847397; called by muse, mutect2, varscan2
- NUP155 | c.1318C>T p.P440S (on ENST00000231498 / NM_153485.3; = p.P381S on NM_004298.4) | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV51534689; called by muse, mutect2, varscan2
- NUP35 | c.160A>T p.I54F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV54559354; called by muse, mutect2, varscan2
- NWD1 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.467); catalogued as COSV60337354; called by muse, varscan2
- NXPE1 | c.1094C>T p.P365L (on ENST00000424269; = p.P223L on NM_152315.5) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.209); catalogued as rs931299886, COSV52633229; called by muse, mutect2, varscan2
- OBSCN | c.3605A>G p.D1202G | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.047); catalogued as COSV52827255; called by muse, mutect2, varscan2
- OLFM3 | c.1000C>T p.H334Y (on ENST00000338858 / NM_001288821.1; = p.H314Y on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/9 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.106); catalogued as COSV58803713; called by mutect2, varscan2
- OMD | c.634G>A p.E212K | Missense Mutation (SNP) | VAF 40/49 reads (82%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65020498; called by muse, mutect2, varscan2
- OPA3 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1487028414, COSV55608144; called by muse, mutect2, varscan2
- OR10H3 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV59944818; called by muse, mutect2, varscan2
- OR10K1 | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as COSV56874086; called by muse, mutect2, varscan2
- OR10T2 | c.628G>A p.V210M | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.096); catalogued as COSV57783410; called by muse, mutect2, varscan2
- OR11G2 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV62133072; called by muse, mutect2, varscan2
- OR13A1 | c.983A>T p.N328I | Missense Mutation (SNP) | VAF 52/76 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.352); catalogued as COSV65573417; called by muse, mutect2, varscan2
- OR13C3 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 37/50 reads (74%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.837); catalogued as COSV66166289; called by muse, mutect2, varscan2
- OR13C8 | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 39/53 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); catalogued as COSV58612437; called by muse, mutect2, varscan2
- OR14C36 | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as COSV58602792; called by muse, mutect2, varscan2
- OR1A1 | c.682C>T p.P228S | Missense Mutation (SNP) | VAF 65/87 reads (75%) | SIFT tolerated (0.06); PolyPhen benign (0.39); catalogued as COSV58404628; called by muse, mutect2, varscan2
- OR1I1 | c.891G>A p.M297I | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV52919097; called by muse, mutect2, varscan2
- OR1N1 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 21/24 reads (88%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV100509616, COSV59196816; called by muse, mutect2, varscan2
- OR1N2 | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); catalogued as rs1369735797, COSV65460313, COSV65461159; called by muse, mutect2, varscan2
- OR1N2 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.271); catalogued as COSV65460357; called by muse, mutect2, varscan2
- OR2A14 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs376721058; called by muse, mutect2, varscan2
- OR2D3 | c.667C>T p.L223F | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV53494883; called by muse, mutect2, varscan2
- OR4C13 | c.60A>C p.K20N | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.003); catalogued as COSV73648924; called by muse, mutect2, varscan2
- OR4D1 | c.295G>A p.A99T | Missense Mutation (SNP) | VAF 148/168 reads (88%) | SIFT tolerated (0.8); PolyPhen benign (0.011); catalogued as COSV52124913, COSV52126126; called by muse, mutect2, varscan2
- OR4S2 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 17/20 reads (85%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs1160317640, COSV56746972; called by muse, mutect2, varscan2
- OR4X1 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.036); catalogued as COSV60723863; called by muse, mutect2, varscan2
- OR51M1 | c.357T>G p.F119L | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.065); catalogued as COSV60785438; called by muse, mutect2, varscan2
- OR51Q1 | c.859C>T p.P287S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56180574; called by muse, mutect2, varscan2
- OR52B2 | c.97C>T p.L33F | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1564844570, COSV73209579; called by muse, mutect2, varscan2
- OR5AK2 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs372725475, COSV58805334; called by muse, mutect2, varscan2
- OR5J2 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.257); catalogued as COSV56623146; called by muse, mutect2, varscan2
- OR5K4 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.458); catalogued as COSV61584317; called by muse, mutect2, varscan2
- OR5M3 | c.508A>T p.I170F | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV56568505; called by muse, varscan2
- OR6C1 | c.679C>T p.P227S | Missense Mutation (SNP) | VAF 41/52 reads (79%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV65573199; called by muse, mutect2, varscan2
- OR6C70 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 19/22 reads (86%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV59245405; called by muse, mutect2, varscan2
- OR6C76 | c.641C>T p.S214F | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs754259018, COSV60389162; called by muse, mutect2, varscan2
- OR6F1 | c.805G>A p.D269N | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT tolerated (0.31); PolyPhen benign (0.019); catalogued as rs267598479, COSV100129224, COSV57468921; called by muse, mutect2, varscan2
- OR6K6 | c.100C>T p.Q34* (on ENST00000368144; = p.Q10* on NM_001005184.1) | Nonsense Mutation (SNP) | VAF 14/69 reads (20%) | catalogued as COSV63744879; called by muse, mutect2, varscan2
- OR6T1 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770876608, COSV58305477; called by muse, mutect2, varscan2
- OR6T1 | c.535C>T p.R179C | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140103246, COSV58305755, COSV58309700; called by muse, mutect2, varscan2
- OR7D2 | c.321T>A p.F107L | Missense Mutation (SNP) | VAF 108/166 reads (65%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.744); catalogued as COSV100713110, COSV60141265; called by muse, mutect2, varscan2
- OR7D4 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.35); catalogued as rs1297429677, COSV100432708, COSV58072546; called by muse, mutect2, varscan2
- OR8D1 | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs776001694, COSV63442129; called by muse, mutect2, varscan2
- OR9A2 | c.435G>A p.W145* | Nonsense Mutation (SNP) | VAF 33/57 reads (58%) | catalogued as COSV100628276; called by muse, mutect2, varscan2
- OR9A2 | c.434G>A p.W145* | Nonsense Mutation (SNP) | VAF 33/57 reads (58%) | catalogued as rs369982496; called by muse, mutect2, varscan2
- OTOF | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV55518989; called by muse, mutect2, varscan2
- OTOL1 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 15/21 reads (71%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs748224624, COSV60006772; called by muse, mutect2, varscan2
- OXTR | c.721G>A p.A241T | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.49); PolyPhen benign (0.062); catalogued as rs745728119, COSV57480937; called by mutect2, varscan2
- PACRGL | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV54844644; called by muse, mutect2, varscan2
- PAGE2B | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.13); catalogued as COSV66611644; called by muse, mutect2, varscan2
- PAK5 | c.1271C>T p.P424L | Missense Mutation (SNP) | VAF 37/86 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV62030186, COSV62040957; called by muse, mutect2, varscan2
- PAPLN | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.531); catalogued as rs1305879414, COSV53723704; called by muse, mutect2, varscan2
- PAPPA | c.3581G>A p.R1194K | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT tolerated (0.45); PolyPhen benign (0.084); catalogued as rs776754324, COSV60291549; called by muse, mutect2, varscan2
- PAPPA2 | c.2872C>T p.Q958* | Nonsense Mutation (SNP) | VAF 25/83 reads (30%) | catalogued as COSV62811181; called by muse, mutect2, varscan2
- PARP9 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV64451870; called by muse, mutect2, varscan2
- PATJ | c.5401G>A p.D1801N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs765172796, COSV64506634; called by mutect2, varscan2
- PAX6 | c.301G>A p.E101K | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD973065, COSV53793659; called by muse, varscan2
- PCARE | c.267G>A p.M89I | Missense Mutation (SNP) | VAF 47/129 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV59058072; called by muse, mutect2, varscan2
- PCDH17 | c.1585C>T p.P529S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.609); catalogued as COSV64979017; called by muse, mutect2, varscan2
- PCDHA11 | c.1748C>T p.S583L | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.12); catalogued as COSV56490096, COSV56519063; called by muse, mutect2, varscan2
- PCDHA6 | c.955C>T p.L319F | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.029); catalogued as COSV100972482; called by muse, mutect2, varscan2
- PCDHAC2 | c.1253C>T p.S418F | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV53868741; called by muse, mutect2, varscan2
- PCDHB1 | c.1705G>A p.G569S | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.111); catalogued as rs1469286299, COSV60633229; called by muse, mutect2, varscan2
- PCDHB2 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.003); catalogued as COSV52037704; called by muse, mutect2, varscan2
- PCDHB9 | c.1613C>T p.S538F | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.059); catalogued as COSV53383622; called by muse, mutect2, varscan2
- PCDHGA10 | c.1951C>T p.Q651* | Nonsense Mutation (SNP) | VAF 32/103 reads (31%) | catalogued as COSV54029735; called by muse, mutect2, varscan2
- PCDHGA4 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.997); catalogued as rs759254327, COSV53907084; called by muse, mutect2, varscan2
- PCDHGA9 | c.1121G>A p.R374Q | Missense Mutation (SNP) | VAF 20/39 reads (51%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.025); catalogued as rs746951310, COSV53976570; called by muse, mutect2, varscan2
- PCDHGA9 | c.1646G>A p.R549K | Missense Mutation (SNP) | VAF 81/134 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as COSV54029709; called by muse, mutect2, varscan2
- PCLO | c.13622G>A p.G4541E | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV61665157; called by muse, mutect2, varscan2
- PCLO | c.6673G>A p.E2225K | Missense Mutation (SNP) | VAF 15/27 reads (56%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV61665165; called by muse, mutect2, varscan2
- PCLO | c.5147G>A p.G1716E | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs773335012, COSV61613244, COSV61665175; called by muse, mutect2
- PCLO | c.4796G>A p.G1599E | Missense Mutation (SNP) | VAF 104/160 reads (65%) | SIFT tolerated (0.24); PolyPhen benign (0.229); catalogued as COSV61632527; called by muse, mutect2, varscan2
- PCLO | c.1926G>A p.M642I | Missense Mutation (SNP) | VAF 9/11 reads (82%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs373145608, COSV61620409; called by muse, mutect2
- PCNX2 | c.6283G>A p.G2095R | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs756070415, COSV50791343; called by muse, mutect2, varscan2
- PCNX2 | c.3239C>T p.A1080V | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT tolerated (0.42); PolyPhen benign (0.023); catalogued as COSV50887126; called by muse, mutect2, varscan2
- PCNX2 | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50854694; called by muse, mutect2, varscan2
- PCNX2 | c.1396C>T p.Q466* | Nonsense Mutation (SNP) | VAF 16/39 reads (41%) | catalogued as COSV50887495; called by muse, mutect2, varscan2
- PCSK5 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV65087286; called by muse, mutect2, varscan2
- PCSK7 | c.2200G>A p.V734M | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.201); catalogued as COSV99639173; called by muse, mutect2, varscan2
- PCYT1B | c.118-1G>A p.X40_splice | Splice Site (SNP) | VAF 9/30 reads (30%) | catalogued as COSV63266511; called by muse, mutect2, varscan2
- PDE11A | c.922T>C p.F308L | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV53708170; called by muse, mutect2, varscan2
- PDE6A | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54931221; called by muse, mutect2, varscan2
- PDGFC | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.903); catalogued as COSV56854861; called by muse, mutect2, varscan2
- PDGFRA | c.2720A>C p.N907T | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV57271956, COSV57273721; called by muse, mutect2, varscan2
- PDZD4 | c.994G>A p.D332N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV51251483; called by muse, mutect2, varscan2
- PDZRN4 | c.1766G>A p.G589E (on ENST00000402685 / NM_001164595.2; = p.G331E on NM_013377.4) | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV54216860; called by muse, mutect2, varscan2
- PEAK1 | c.3811C>T p.P1271S | Missense Mutation (SNP) | VAF 54/92 reads (59%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV56942896; called by muse, mutect2, varscan2
- PELP1 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 13/18 reads (72%) | SIFT tolerated (0.47); PolyPhen benign (0.024); catalogued as COSV52592294; called by muse, mutect2, varscan2
- PELP1 | c.1363G>A p.G455R | Missense Mutation (SNP) | VAF 57/67 reads (85%) | SIFT tolerated (0.05); PolyPhen benign (0.399); catalogued as COSV52592314; called by muse, mutect2, varscan2
- PER1 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 18/21 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100424786; called by muse, mutect2, varscan2
- PIWIL2 | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 45/93 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.521); catalogued as COSV63253985; called by muse, mutect2, varscan2
- PIWIL2 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 40/73 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs199877180, COSV63251747; called by muse, mutect2, varscan2
- PIWIL3 | c.1216G>A p.G406S | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100177559, COSV59998123; called by muse, mutect2, varscan2
- PLA2G2E | c.56G>A p.G19E | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64290936; called by muse, mutect2, varscan2
- PLA2G4D | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 38/52 reads (73%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as rs774177182, COSV51823759; called by muse, mutect2, varscan2
- PLCB4 | c.157G>A p.E53K | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.057); catalogued as rs768015317, COSV53811096; called by muse, mutect2, varscan2
- PLCB4 | c.2548G>A p.D850N | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.971); catalogued as COSV53817607; called by muse, mutect2, varscan2
- PLCH1 | c.244C>T p.H82Y (on ENST00000340059 / NM_001130960.2; = p.H94Y on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/47 reads (66%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV58209948; called by muse, varscan2
- PLEKHG7 | c.1619G>A p.G540E | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.664); catalogued as rs1179483150, COSV60822792; called by muse, mutect2, varscan2
- PLEKHH3 | c.2168G>A p.R723K | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV52219604; called by muse, mutect2, varscan2
- PLEKHS1 | c.808G>A p.E270K (on ENST00000369310 / NM_182601.1; = p.E276K on NM_024889.5) | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.73); catalogued as COSV63056424; called by mutect2, varscan2
- PLG | c.1294G>A p.D432N | Missense Mutation (SNP) | VAF 45/53 reads (85%) | SIFT deleterious (0.02); PolyPhen benign (0.274); catalogued as rs770460362, CM152181, COSV51980494, COSV51981117; called by muse, mutect2, varscan2
- PLSCR4 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.114); catalogued as COSV61608173, COSV61609038; called by muse, mutect2, varscan2
- PMF1-BGLAP | c.543C>T p.S181= | Splice Region (SNP) | VAF 23/52 reads (44%) | catalogued as COSV52746707; called by muse, mutect2, varscan2
- PNMA3 | c.1355C>T p.A452V | Missense Mutation (SNP) | VAF 74/140 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.044); catalogued as COSV64722972; called by muse, mutect2, varscan2
- PNMA5 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 45/131 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782287773, COSV62625584; called by muse, mutect2, varscan2
- PNP | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT tolerated (0.74); PolyPhen benign (0.001); catalogued as rs199763463, COSV64092289; called by muse, mutect2, varscan2
- PODNL1 | c.163G>A p.G55S | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV54309835; called by muse, mutect2, varscan2
- POSTN | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101123451; called by muse, mutect2, varscan2
1,014 further variants in this file (382 protein-altering or splice-affecting, 595 silent, 37 other) are not listed here.
